Gene-level copy-number profile of tumor specimen TCGA-41-3915-01A from TCGA case TCGA-41-3915, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.0 years (17,880 days).
Specimen TCGA-41-3915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ed02a29d-d035-462c-8f75-dd24ffadee4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-41-3915-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d608f38d-0ef0-43ac-86cd-090504576ac9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1; copy number 2: 15,388; copy number 3: 30,846; copy number 4: 13,397; copy number 5: 28; copy number 6: 57; copy number 7: 75; copy number 8: 14; copy number 9: 2; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-41-3915-01A-01D-1224-01): tumor purity 0.77, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,296,162–48,599,436, 7 genes (within-gene range 0–2): RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 94 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:52,110,839–52,460,959, 1 gene, copy number 7 (within-gene range 3–7): ST18.
- chr8:52,194,362–54,192,035, 33 genes, copy number 7: AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1.
- chr8:73,939,169–74,321,540, 12 genes, copy number 7: ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1.
- chr8:74,347,757–74,376,793, 2 genes, copy number 7: AC103952.1, Y_RNA.
- chr8:75,376,709–75,566,834, 2 genes, copy number 7: PKMP4, HNF4G.
- chr8:76,904,591–77,001,044, 3 genes, copy number 7: AC023200.1, MIR3149, PEX2.
- chr8:79,769,372–79,930,892, 3 genes, copy number 7 (within-gene range 4–7): AC036214.1, RNU7-85P, AC036214.4.
- chr8:89,412,621–89,757,812, 2 genes, copy number 7 (within-gene range 3–7): KRT8P4, AF117829.1.
- chr8:94,879,770–94,896,678, 3 genes, copy number 10: CCNE2, AC087752.4, AC087752.1.
- chr8:112,148,742–112,148,825, 1 gene, copy number 7: RNU4-37P.
- chr8:112,446,575–112,539,317, 2 genes, copy number 9: AC024996.1, RPL30P16.
- chr8:131,712,512–132,675,592, 8 genes, copy number 7–8: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6.
- chr21:24,154,871–24,547,942, 3 genes, copy number 8: AP000470.1, LINC01689, LINC01684.
- chr21:27,143,344–27,985,295, 9 genes, copy number 8: GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1.
- chr21:32,402,511–32,612,865, 1 gene, copy number 7 (within-gene range 4–7): CFAP298-TCP10L.
- chr21:32,497,967–32,771,792, 9 genes, copy number 7 (within-gene range 4–7): TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1, PAXBP1-AS1, PAXBP1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
